Gene-level copy-number profile of tumor specimen TCGA-CH-5767-01A from TCGA case TCGA-CH-5767, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,287 days).
Specimen TCGA-CH-5767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.81320fe9-9dd5-4629-a0db-66607294a19b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CH-5767-11B (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c647af83-d006-47e3-b1c9-6f192b2c80db

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 4,755; copy number 2: 53,565; copy number 3: 787; copy number 4: 651.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CH-5767-01A-11D-1785-01): tumor purity 0.83, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:125,823,108–125,823,315, 1 gene: AC097499.1.
- chr2:137,715,332–140,221,485, 30 genes: Y_RNA, HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:140,234,737–140,234,923, 1 gene: AC092156.1.
- chr2:163,743,913–166,611,482, 30 genes (within-gene range 0–1): AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F, AC019197.1, RNA5SP110, RNA5SP111, SLC38A11, SCN3A, SCN2A, MAPRE1P3, AC011303.1, CSRNP3, GALNT3, AC009495.3, AC009495.1, AC009495.2, TTC21B, TTC21B-AS1, SCN1A-AS1, SCN1A, Y_RNA, RN7SKP152, SCN9A, SCN7A, AC074101.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,375. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
